Gene-level copy-number profile of tumor specimen ALCH-B2PC-TTP1-A from ALCHEMIST case ALCH-B2PC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.1 years (24,859 days).
Specimen ALCH-B2PC-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2ab34142-909f-4734-8327-a1762b59ee6d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2PC-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/1112e982-5943-40f1-9dcf-e13a69378997

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 79; copy number 1: 2,353; copy number 2: 55,249; copy number 3: 700; copy number 4: 6; copy number 5: 4; copy number 7: 2; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 79 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:131,527,675–131,536,988, 2 genes: CCDC74A, MED15P4.
- chr2:240,686,334–240,690,414, 1 gene: AC011298.1.
- chr3:46,694,528–46,710,886, 1 gene: TMIE.
- chr3:50,191,610–50,197,696, 1 gene: GNAT1.
- chr4:1,210,120–1,249,953, 2 genes (within-gene range 0–2): CTBP1-AS, CTBP1.
- chr4:3,463,306–3,532,446, 2 genes: DOK7, LRPAP1.
- chr4:8,592,660–8,619,759, 1 gene (within-gene range 0–1): CPZ.
- chr7:6,497,462–6,551,436, 1 gene: GRID2IP.
- chr9:39,983,793–40,106,611, 1 gene (within-gene range 0–2): AL772307.1.
- chr9:40,105,822–40,122,540, 2 genes: AL773545.3, CDRT15P14.
- chr9:130,892,707–130,945,520, 3 genes: QRFP, FIBCD1, AL161733.1.
- chr10:48,443,836–48,445,820, 1 gene: AC016397.2.
- chr11:61,746,493–61,788,518, 2 genes (within-gene range 0–2): MYRF-AS1, MYRF.
- chr12:57,194,504–57,194,576, 1 gene (within-gene range 0–2): MIR1228.
- chr12:111,304,142–111,304,209, 1 gene (within-gene range 0–2): MIR6760.
- chr13:41,287,741–41,288,320, 1 gene: RAC1P3.
- chr13:109,400,696–109,401,641, 1 gene: LINC00399.
- chr14:102,545,254–102,555,826, 1 gene: LINC02323.
- chr14:104,579,764–104,590,515, 2 genes (within-gene range 0–1): C14orf180, BX927359.1.
- chr15:25,182,385–25,250,940, 38 genes (within-gene range 0–1): SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:93,035,273–93,089,204, 2 genes: RGMA, YBX2P2.
- chr16:29,613,103–29,636,328, 3 genes: SLC7A5P1, CA5AP1, AC009086.1.
- chr16:75,226,074–75,228,197, 1 gene (within-gene range 0–2): AC009078.2.
- chr17:32,280,387–32,280,953, 1 gene (within-gene range 0–2): AC026620.1.
- chr17:41,626,327–41,640,199, 1 gene: KRT42P.
- chr21:45,981,769–46,005,050, 1 gene: COL6A1.
- chr22:18,733,914–18,757,906, 1 gene: FAM230E.
- chr22:29,720,003–29,731,833, 1 gene (within-gene range 0–2): CABP7.
- chr22:46,112,749–46,113,768, 3 genes (within-gene range 0–2): MIRLET7A3, MIR4763, MIRLET7B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:197,311,393–197,312,740, 1 gene, copy number 5: AC010746.2.
- chr2:242,175,181–242,175,634, 1 gene, copy number 7: RPL23AP88.
- chr8:143,977,153–144,047,114, 3 genes, copy number 5: PARP10, GRINA, SPATC1.
- chr15:32,359,538–32,367,784, 1 gene, copy number 7: AC139426.2.
- chr15:32,446,674–32,446,964, 1 gene, copy number 10: RN7SL539P.

Autosomal genes at a single copy (total copy number 1): 2,353. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
